Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H5, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H5-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

CASE NUMBER:

DIAGNOSIS: Adrenal gland, left (adrenalectomy): Pheochromocytoma;
adrenal cortical adenoma.

Final

Final Results

NOTE:

CLINICAL INFORMATION: Brief Clinical History: Women with left adrenal
pheochromocytoma

Specimen Taken For Protocol: - Yes Allocate Order
to Protocol:

PROCEDURE: Operative Findings: Left adrenal lesion Post-Operative
Diagnosis: same
Pre-Operative Diagnosis: Pheo

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh in a container labeled with the
patient's name, medical record number, and "left adrenal" is an
adrenalectomy specimen measuring 14 x 7.5 x 5.4 cm overall and weighing
77.2 grams, surrounded by minimal adipose tissue. There is a red-yellow
soft tissue nodule measuring 7.5 x 5.4 x 3.8 cm, which is encapsulated.
The outer surface of the specimen is inked in blue. The specimen is
bisected revealing a dark red-yellow, cystic, lobulated, variegated cut
surface with no grossly identifiable adrenal gland. An aggregate of 2.5
x 2.0 x 0.3 cm tissue not involving the inked margin is procured for Dr.
The remainder of the specimen is sent to Surgical
Pathology. Pictures are taken. The procurement was performed
The specimen is received in Surgical
Pathology and is consistent with the above description. Serial
sectioning the specimen reveals a small amount of yellow adrenocortical
tissue surrounding the tumor. Representative sections of tumor are
submitted in cassettes A-H. Representative sections of
normal-appearing adrenal cortex are submitted in cassettes
I-J.

Gross dictated by

No consultants

#

Requested By:

Do not file in Medical Record

[page 2 of 2]
#

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file cfe566ec-0e04-46f2-9386-51130c484b0d (TCGA-QR-A6H5.9DE42B9C-FF8E-4DCE-8754-3F611B7FD610.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).